Surgical pathology report (de-identified scan), TCGA case TCGA-06-6693, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-6693-01A (Primary Tumor).

[page 1 of 2]
TCGA-06-6693

PATHOLOGICAL DIAGNOSIS:

BRAIN, LEFT TEMPORAL LOBE, BIOPSY EXCISION: GLIOBLASTOMA MULTIFORME.

Operation/Specimen: 1. Lt. cerebral hemisphere brain tumor. 2.
Posterior
temporal lobe.

Clinical History and Pre-Op Dx:

GROSS PATHOLOGY: Specimen is received in two containers labeled with
the
patient's name, MRN and "#1 "left lobe tumor", and #2 "posterior
temporal
lobe".

Large fragments of an irregularly shaped grayish partly necrotic white
tissue resembling brain are present in both containers. The first one
measures 3.8 x 2.2 x 1.9 cm. in greatest dimensions. Representative
samples
of this tissue are submitted in cassettes labeled 1-3. The second
container
encloses a fragment of cerebral tissue that measures 4.2 x 2.5 x 2.1
cm. in
greatest dimensions. Some areas of necrosis, hemorrhage, and
infiltration
by what appears to be a tumor are observed throughout most of this
specimen,
particularly in the portion of the lobe that corresponds to the
subcortical
white matter fibers. Representative samples of this second specimen
are
submitted in cassettes labeled 4 to 7.

MICROSCOPIC: Almost all sections show infiltration by what appears to
be a
very cellular tumor containing abundant atypical mitotic figures,
markedly
hyperplastic blood vessels and large areas of coagulation necrosis.
Individual cells are relatively small and display minimum cytoplasm.
The
nucleus is relatively large and hypochromatic. In a few areas the
nuclear

[page 2 of 2]
chromatin features appear similar to those of adult astrocytes, however, in most places the tumor is markedly anaplastic and individual cells show very little resemblance to any adult glial cell. Nevertheless, on the basis of the nuclear features of the best differentiated elements of the tumor, I interpret these cells as being derived from astrocytes.

SPECIAL STAINS:.

Source: NCI Genomic Data Commons file 961af563-54c5-4199-acf2-b90fd36c82a0 (TCGA-06-6693.73D0F748-136F-4000-AE46-DE505F8BEE47.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).